CCDI case PBBPLT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5faa17ad-b1fb-48f7-bbae-743aa1ba2f65

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,118 days).

Biospecimens (3 samples)
- Sample 0DE7CV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE7E4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE7FM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
